FM case AD15197 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Squamous Cell Neoplasms; Primary site: Rectum.
https://portal.gdc.cancer.gov/cases/6e9877fa-2c62-4502-8980-811c72ed8389

Female, 35.9 years: Squamous cell carcinoma, NOS (ICD-O-3 8070/3) of the rectum; metastasis biopsied or resected from the lymph node. Tumor nuclei on the sequenced sample's slide: 50% (pathologist estimate recorded by GDC). Sample type: Metastatic.
